Gene-level copy-number profile of tumor specimen TCGA-XN-A8T3-01A from TCGA case TCGA-XN-A8T3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.9 years (24,810 days).
Specimen TCGA-XN-A8T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.eb52e178-42f6-4146-bcae-f1e579588fe5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XN-A8T3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6725d448-262c-4e72-b2a2-eac063577448

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 23,121; copy number 2: 30,536; copy number 3: 6,012; copy number 5: 89; copy number 6: 2; copy number 8: 36; copy number 17: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XN-A8T3-01A-11D-A36N-01): tumor purity 0.19, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,824,213, 20 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 129 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,053,450–31,083,109, 2 genes, copy number 6: HCG22, RNU6-1133P.
- chr6:31,611,083–32,407,763, 89 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:33,620,365–34,883,138, 36 genes, copy number 8 (within-gene range 1–8): ITPR3, UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3, LINC01016, AL138889.2, AL138889.1, MIR7159, MIR1275, GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA.
- chr6:35,943,516–36,024,868, 2 genes, copy number 17 (within-gene range 1–17): SLC26A8, DPRXP2.

Autosomal genes at a single copy (total copy number 1): 20,700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
